Somatic mutation profile of tumor specimen TCGA-S7-A7WV-01A (aliquot TCGA-S7-A7WV-01A-11D-A35I-08) from TCGA case TCGA-S7-A7WV, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 35.3 years (12,893 days).
Specimen TCGA-S7-A7WV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c05b59a-bcd3-4f66-9d27-c16bebb5621f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WV-10A (Blood Derived Normal), aliquot TCGA-S7-A7WV-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f943c84-3847-4993-a722-e5d4aa1f0249

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX21 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2
- C20orf96 | c.753C>G p.R251= (on ENST00000360321 / NM_153269.3; = p.R250= on NM_080571.1) | Silent (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
